Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U5-01A (Primary Tumor).

[page 1 of 5]
SPECIMEN(S):

- A. LEFT AXILLARY SENTINEL LYMPH NODE #1
- B. LEFT AXILLARY SENTINEL NODE #2
- C. RIGHT AXILLARY SENTINEL LYMPH NODE #1
- D. RIGHT AXILLARY SENTINEL LYMPH NODE #2
- E. EXCISION MID BACK MELANOMA

CLINICAL HISTORY:

None provided.

ICD-0-3
Melanoma, NOS 8120/3
Site: skin, back C49.6

PRE-OPERATIVE DIAGNOSIS:

None provided.

fw
10/10/12

GROSS DESCRIPTION:

A. LEFT AXILLARY SENTINEL LYMPH NODE #1

Received in formalin labeled with the patient's identification and 'left axillary sentinel lymph node #1' is a tan pink lymph node 1.6 x 1.5 x 1.4 cm. The specimen is serially sectioned. Toto A1.

B. LEFT AXILLARY SENTINEL LYMPH NODE #2

Received in formalin labeled with the patient's identification and 'left axillary sentinel lymph node #2' is a tan pink lymph node 0.7 x 0.6 x 0.5 cm. The specimen is serially sectioned. Toto B1.

C. RIGHT AXILLARY SENTINEL LYMPH NODE #1

Received in formalin labeled with the patient's identification and 'right axillary sentinel lymph node #1' is a tan pink lymph node 2.6 x 1.8 x 1.6 cm. The specimen is serially sectioned. Toto C1.

[page 2 of 5]
D. RIGHT AXILLARY SENTINEL LYMPH NODE #2

Received in formalin labeled with the patient's identification and 'right axillary sentinel lymph node #2' is a tan pink lymph node 0.7 x 0.6 x 0.6 cm. The specimen is serially sectioned. Toto D1.

E. EXCISION MID BACK MELANOMA

Received fresh labeled with the patient's identification and 'excision mid back melanoma' is an oriented tan pink skin excision 16 x 5.7 cm excised to a depth of 3.5 cm. The skin surface is remarkable for a centrally located raised well demarcated pigmented lesion 1.8 x 1.5 cm, 1.5 cm from the closest inferior margin. Gross photographs are taken. Ink code: superior-blue, inferior-orange. The specimen is serially sectioned from presumptive medial to lateral. The lesion does not grossly appear to involve the underlying adipose tissue. A portion of the specimen is submitted for tissue procurement. Representatively submitted:

E1: presumptive medial margin

E2: presumptive lateral margin

E3-E4: shave of superior margin- closest to lesion

E5-E6: shave of inferior margin- closest to lesion

E7-E8: one section of lesion bisected

E9-E10: one section of lesion bisected

E11-E12: one section of lesion bisected

E13-E14: one section of lesion bisected

E15-E16: one section of lesion bisected

DIAGNOSIS:

A. LYMPH NODE, SENTINEL - LEFT AXILLA, EXCISION:

- METASTATIC MELANOMA TO ONE LYMPH NODE (1/1).

B. LYMPH NODE, SENTINEL - LEFT AXILLA, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTATIC TUMOR (0/1).

C. LYMPH NODE, SENTINEL - RIGHT AXILLA, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTATIC TUMOR (0/1).

[page 3 of 5]
D. LYMPH NODE, SENTINEL - RIGHT AXILLA, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTATIC TUMOR (0/1).

E. SKIN, MID BACK, EXCISION:

- RESIDUAL MALIGNANT MELANOMA
- 3.0 MM IN DEPTH
- CLARK'S LEVEL IV
- ALL MARGINS ARE NEGATIVE FOR MALIGNANCY
- THE MELANOMA IS 1.5 CM FROM THE INFERIOR MARGIN (CLOSEST MARGIN).
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- ASSOCIATED WITH MARKED CHRONIC INFLAMMATION AND MELANOPHAGES.

COMMENT:

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A1

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

A103,MELAN-A

Positive

S-100

Positive

[page 4 of 5]
Material: Block B1

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

A103,MELAN-A

Negative

S-100

Negative

Material: Block C1

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

A103,MELAN-A

Negative

S-100

Negative

Material: Block D1

[page 5 of 5]
Population: Tumor Cells

Stain/Marker:

Result:

Comment:

A103,MELAN-A

Negative

S-100

Negative

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

ADDENDUM: The residual melanoma is focally ulcerated.

Dx/Path/Synchronous Primary noted		

Source: NCI Genomic Data Commons file 897cdad5-2c84-4177-b801-fd7b3c9ce74d (TCGA-GN-A4U5.4FC4C20F-487A-432C-8845-9298636A5098.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).